Somatic mutation profile of cancer-model specimen HCM-BROD-0758-C43-85N (Adherent Cell Line, passage 8; aliquot HCM-BROD-0758-C43-85N-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0758-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 55.3 years (20,195 days).
Specimen HCM-BROD-0758-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef25bb39-b4f8-44b5-a304-1efbf8656433.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0758-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0758-C43-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/439e7d20-fc00-4351-afdc-9bc5525f82ba

The open-access MAF lists 394 somatic variants for this specimen: 248 protein-altering or splice-affecting, 129 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 129, Nonsense Mutation 16, Intron 9, 5'UTR 3, 3'UTR 3, Splice Region 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.2039G>A p.W680* | Nonsense Mutation (SNP) | VAF 160/343 reads (47%) | catalogued as rs113994129, CM960016; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.4831C>T p.R1611* | Nonsense Mutation (SNP) | VAF 166/240 reads (69%) | catalogued as rs1554236040, COSV51670259; ClinVar: pathogenic; called by muse, varscan2
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 620/621 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 273/426 reads (64%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- SCN1A | c.4811G>A p.W1604* (on ENST00000303395 / NM_001202435.3; = p.W1593* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 94/422 reads (22%) | catalogued as rs794726800, CM1511236, COSV57668685; ClinVar: pathogenic; called by muse, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 126/335 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2, varscan2
- ABHD16B | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 297/442 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs1449405394, COSV53862321; called by muse, varscan2
- ABI3BP | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 107/368 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs770109610, COSV52528036; called by muse, varscan2
- ACSM1 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 139/288 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs905851561, COSV54632777; called by muse, varscan2
- ADAMTS7 | c.4013C>T p.P1338L | Missense Mutation (SNP) | VAF 120/894 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1331914241; called by muse, varscan2
- ADAT3 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 286/571 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as rs752745048; called by muse, varscan2
- ADCY10 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 136/276 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs779053477, COSV63240979; called by muse, varscan2
- AFM | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 165/336 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867565889, COSV56921393; called by muse, mutect2, varscan2
- AKR1C4 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 195/196 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554798075, COSV99578659; called by muse, varscan2
- AKR1D1 | c.906G>C p.L302F | Missense Mutation (SNP) | VAF 84/930 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV54338845; called by muse, mutect2
- AMPD2 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 281/562 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.543); catalogued as rs778310718; called by muse, mutect2, varscan2
- ANKS1B | c.3649C>T p.R1217C (on ENST00000547776 / NM_152788.4; = p.R383C on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/390 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761350003, COSV100227188; called by muse, varscan2
- ARHGAP6 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 1050/1344 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV100272745; called by muse, varscan2
- ASB5 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 170/356 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs1167022895; called by muse, varscan2
- BTNL3 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 269/269 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61564523; called by muse, mutect2, varscan2
- CACNA1E | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 184/363 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62385594; called by muse, varscan2
- CATSPER1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 123/445 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs774801543; called by muse, varscan2
- CCR2 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 209/347 reads (60%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.589); catalogued as COSV52749045; called by muse, mutect2, varscan2
- CEP128 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 162/241 reads (67%) | catalogued as rs780056351, COSV99825760; called by muse, varscan2
- CFAP91 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 108/178 reads (61%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.844); catalogued as COSV56341066; called by muse, mutect2, varscan2
- CHP2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 211/445 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs761363152; called by muse, mutect2, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 171/635 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, mutect2, varscan2
- COL17A1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 162/163 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100793412; called by muse, varscan2
- COL4A4 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 230/306 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339269673, COSV61633544; called by muse, mutect2, varscan2
- COL5A3 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 183/316 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs139738587; called by muse, varscan2
- COL6A5 | c.6016G>A p.D2006N (on ENST00000312481; = p.D2002N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs914947395, COSV99592741; called by muse, varscan2
- COMMD5 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 334/605 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs546989702; called by muse, varscan2
- CRB1 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 160/333 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs867230786, COSV66334082; called by muse, mutect2, varscan2
- CRISP2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV59253803; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 176/341 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, mutect2, varscan2
- DNAH5 | c.7273C>T p.R2425C | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs376707969; called by muse, varscan2
- ECE1 | c.2147C>T p.S716F | Missense Mutation (SNP) | VAF 187/376 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV51665767; called by muse, varscan2
- EEF1AKMT3 | c.336C>G p.I112M | Missense Mutation (SNP) | VAF 472/2176 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as COSV55744230; called by muse, mutect2, varscan2
- ELAPOR1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1271600009; called by muse, mutect2, varscan2
- EREG | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 150/304 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs866675158, COSV55260744; called by muse, mutect2, varscan2
- ERICH3 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs1248020610; called by muse, varscan2
- ESAM | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 122/406 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54034925; called by muse, varscan2
- FAT4 | c.13867G>A p.D4623N | Missense Mutation (SNP) | VAF 264/540 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58710120; called by muse, varscan2
- FGG | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 167/356 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60196319; called by muse, varscan2
- FSIP2 | c.19924C>T p.R6642* | Nonsense Mutation (SNP) | VAF 164/216 reads (76%) | catalogued as rs1208600297, COSV104420935; called by muse, varscan2
- FTMT | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV58419945; called by muse, varscan2
- GABRG1 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 132/254 reads (52%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.593); catalogued as rs1408329621, COSV54960467; called by muse, mutect2, varscan2
- GH2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 256/256 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs771557060; called by muse, varscan2
- GIPC2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 176/322 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771262251; called by muse, mutect2, varscan2
- GOLGA6L4 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 1064/1182 reads (90%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs1432337504; called by muse, varscan2
- GRIN2B | c.4036G>A p.E1346K | Missense Mutation (SNP) | VAF 261/532 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as rs766060662, COSV101663026; called by muse, varscan2
- IGSF22 | c.2521G>A p.E841K (on ENST00000319338; = p.E942K on NM_173588.4) | Missense Mutation (SNP) | VAF 234/467 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.963); catalogued as COSV55010454; called by muse, varscan2
- IRAK3 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 145/304 reads (48%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV99706443; called by muse, mutect2, varscan2
- JUP | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60278932; called by muse, varscan2
- KCNK5 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 285/593 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.882); catalogued as rs748673096, COSV63988552; called by muse, varscan2
- KCNT1 | c.1010G>T p.R337L (on ENST00000488444; = p.R356L on NM_020822.3) | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV53700894; called by muse, varscan2
- KCNT2 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54106340; called by muse, varscan2
- KLK2 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 194/382 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1434880603; called by muse, mutect2, varscan2
- KRT4 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 97/300 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs758810156, COSV53407310; called by muse, varscan2
- LAMA2 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV70355091; called by muse, varscan2
- LETM1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 94/348 reads (27%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1040223952, COSV57103100; called by muse, varscan2
- LILRB4 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1014800420; called by muse, mutect2, varscan2
- LIN28A | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 157/358 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1557427180; called by muse, mutect2, varscan2
- LIPM | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs532626102; called by muse, mutect2, varscan2
- MAGEC1 | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 224/332 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs143297640, COSV53573257, COSV53573679; called by muse, varscan2
- MAMDC2 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101015129, COSV65858391; called by muse, varscan2
- MAP3K13 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53983436; called by muse, varscan2
- MCTP2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 121/535 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV59147313; called by muse, mutect2, varscan2
- MEPE | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as COSV63073518; called by muse, varscan2
- MIA2 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as rs144877390; called by muse, varscan2
- MORC1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 118/213 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51717195; called by muse, mutect2, varscan2
- MUC12 | c.15307G>A p.E5103K (on ENST00000379442; = p.E4960K on NM_001164462.1) | Missense Mutation (SNP) | VAF 245/749 reads (33%) | SIFT tolerated (0.26); catalogued as COSV65199299; called by muse, mutect2, varscan2
- MUC16 | c.33007C>T p.L11003F | Missense Mutation (SNP) | VAF 238/535 reads (44%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); catalogued as COSV67464632; called by muse, mutect2, varscan2
- MUC16 | c.5816C>T p.S1939L | Missense Mutation (SNP) | VAF 128/256 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV67457357; called by muse, varscan2
- MYRF | c.562C>T p.P188S (on ENST00000278836 / NM_001127392.3; = p.P179S on NM_013279.4) | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs964270558; called by mutect2, varscan2
- NAA11 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 250/499 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs745372449, COSV54514317, COSV99727364; called by muse, varscan2
- NEFL | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs57848467, CM032289; ClinVar: not provided / uncertain significance; called by muse, varscan2
- NIPAL1 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 145/319 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV55005885; called by muse, mutect2, varscan2
- NPTX2 | c.1069-1G>A p.X357_splice | Splice Site (SNP) | VAF 178/569 reads (31%) | catalogued as COSV99674599; called by muse, mutect2, varscan2
- OGFOD2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 173/471 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1566208456; called by muse, varscan2
- OR10A2 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 254/547 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV56298732; called by muse, mutect2, varscan2
- OR2T2 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 144/364 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61618765; called by muse, mutect2, varscan2
- PCDHB10 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 262/263 reads (100%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs189437073, COSV53379211; called by muse, varscan2
- PCOLCE2 | c.378G>A p.M126I | Missense Mutation (SNP) | VAF 110/325 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV55998856; called by muse, varscan2
- PDE3A | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62973135; called by muse, varscan2
- PDE8B | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as rs750904456, COSV53740558; called by muse, varscan2
- PHF21B | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 145/417 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs945696109; called by muse, varscan2
- PHF3 | c.5326C>T p.P1776S | Missense Mutation (SNP) | VAF 126/368 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1445822408, COSV50313855; called by muse, varscan2
- PIWIL2 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs368245312; called by muse, varscan2
- PKHD1L1 | c.8635C>G p.R2879G | Missense Mutation (SNP) | VAF 79/430 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV101006194; called by muse, mutect2, varscan2
- PLCL2 | c.1381C>T p.R461* (on ENST00000615277 / NM_001144382.2; = p.R335* on NM_015184.5) | Nonsense Mutation (SNP) | VAF 85/256 reads (33%) | catalogued as COSV67621776; called by muse, varscan2
- PLXNA3 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 191/635 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1357426105; called by muse, varscan2
- PNPLA6 | c.4082G>A p.R1361Q (on ENST00000414982 / NM_001166111.2; = p.R1313Q on NM_006702.5) | Missense Mutation (SNP) | VAF 193/490 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs779790168; called by muse, mutect2, varscan2
- PPP1R3A | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 186/712 reads (26%) | catalogued as COSV52882407; called by muse, mutect2, varscan2
- PRAMEF4 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 523/550 reads (95%) | SIFT tolerated (0.22); PolyPhen benign (0.117); catalogued as rs778299374; called by muse, varscan2
- PROK2 | c.350G>A p.R117Q (on ENST00000295619 / NM_001126128.2; = p.R96Q on NM_021935.4) | Missense Mutation (SNP) | VAF 97/345 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs1396253995, COSV55208496; called by muse, varscan2
- PRRC2C | c.8066C>T p.P2689L (on ENST00000367742; = p.P2687L on NM_015172.4) | Missense Mutation (SNP) | VAF 127/287 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58913028; called by muse, varscan2
- PRUNE1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 112/224 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV54958885; called by muse, varscan2
- PTPRB | c.3842G>A p.W1281* | Nonsense Mutation (SNP) | VAF 87/296 reads (29%) | catalogued as COSV54232440; called by muse, varscan2
- PTPRQ | c.508G>A p.E170K (on ENST00000616559; = p.E128K on NM_001145026.2) | Missense Mutation (SNP) | VAF 134/135 reads (99%) | SIFT tolerated (0.3); PolyPhen benign (0.108); catalogued as rs1479476966; called by muse, mutect2, varscan2
- RABEP2 | c.1055T>G p.V352G | Missense Mutation (SNP) | VAF 192/452 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV62869951; called by muse, mutect2, varscan2
- RASL12 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 132/660 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs769143677; called by muse, mutect2, varscan2
- RBMXL2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 358/757 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1228883467; called by muse, varscan2
- RGPD4 | c.4121G>A p.W1374* | Nonsense Mutation (SNP) | VAF 106/528 reads (20%) | catalogued as COSV61749561; called by muse, varscan2
- RNASET2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs774543357; called by muse, mutect2, varscan2
- RTN3 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 144/246 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs772966959; called by muse, mutect2, varscan2
- RUNX1T1 | c.797G>A p.R266Q (on ENST00000265814 / NM_001198628.1; = p.R239Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 217/496 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359364143, COSV99750353; called by muse, mutect2, varscan2
- SBNO1 | c.1124C>T p.S375L (on ENST00000420886; = p.S374L on NM_018183.5) | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); catalogued as rs147276203, COSV57345269; called by muse, mutect2, varscan2
- SGCE | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 184/536 reads (34%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.044); catalogued as rs761677071, COSV56016470; called by muse, mutect2, varscan2
- SIRPG | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 189/189 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1281567353, COSV53805960; called by muse, varscan2
- SLC2A2 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 155/243 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100049134, COSV58586598; called by muse, mutect2, varscan2
- SLC6A14 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 125/367 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64147231; called by muse, mutect2, varscan2
- SPEF2 | c.4961G>A p.G1654E | Missense Mutation (SNP) | VAF 96/290 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57428581; called by muse, varscan2
- SPOCD1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 218/436 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs561311491, COSV57096942; called by muse, varscan2
- ST18 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 192/362 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs1180624281, COSV52488986; called by muse, mutect2, varscan2
- SULT1C4 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 272/341 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs750911106, COSV55597757; called by muse, varscan2
- SYN3 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 263/412 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs781427098, COSV60506596; called by muse, mutect2, varscan2
- SYT5 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 195/358 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62830068; called by muse, varscan2
- TAOK3 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 621/800 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1277510978, COSV101183685; called by muse, mutect2, varscan2
- TBC1D14 | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs1350297845; called by muse, varscan2
- TCAIM | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs765468418, COSV61240135; called by muse, mutect2, varscan2
- TENM2 | c.3845G>A p.S1282N | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as rs1163257568; called by muse, mutect2, varscan2
- TENT4B | c.1277G>A p.R426Q (on ENST00000561678 / NM_001365323.2; = p.R411Q on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV62549294; called by muse, varscan2
- TGM1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 246/396 reads (62%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); catalogued as rs1445996067; called by muse, varscan2
- TOP3A | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 144/456 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs757039121, COSV58178210, COSV58178822; called by muse, varscan2
- TP53 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 294/296 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52665474, COSV52751752, COSV52987532; called by muse, varscan2
- TRAV7 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs946727967; called by muse, varscan2
- TRIML1 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 213/483 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1316000776, COSV60194018, COSV60196036; called by muse, mutect2, varscan2
- TTC6 | c.2534A>T p.D845V | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs758262904; called by muse, mutect2, varscan2
- TTN | c.4112G>A p.G1371E (on ENST00000591111; = p.G1325E on NM_003319.4) | Missense Mutation (SNP) | VAF 211/298 reads (71%) | PolyPhen probably damaging (1); catalogued as rs267599090, COSV60214092; called by muse, varscan2
- UBQLN3 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 240/515 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.352); catalogued as rs773974129; called by muse, mutect2, varscan2
- UCKL1 | c.303C>T p.I101= | Splice Region (SNP) | VAF 150/226 reads (66%) | catalogued as rs201407701; called by muse, varscan2
- WDR87 | c.7984G>A p.E2662K | Missense Mutation (SNP) | VAF 202/384 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as COSV58192643; called by muse, varscan2
- ZNF479 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 106/423 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs535878108, COSV58635779; called by muse, mutect2, varscan2
- ZNF490 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 119/311 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs539425301, COSV61008916; called by muse, mutect2, varscan2
- ZNF517 | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 323/737 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs754474284; called by muse, varscan2
- ZNF777 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 322/1416 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99925400; called by muse, varscan2
- ZNF831 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 144/447 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1003756292; called by muse, varscan2
- ZNF831 | c.2972G>A p.S991N | Missense Mutation (SNP) | VAF 141/472 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.176); catalogued as rs1228989095; called by muse, varscan2
- ACSM3 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 169/335 reads (50%) | called by muse, mutect2, varscan2
- ADAM15 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 171/366 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ANK3 | c.4426G>A p.G1476R (on ENST00000280772 / NM_001320874.2; = p.G601R on NM_001149.3) | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGEF1 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ARMCX5 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, varscan2
- BAP1 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 244/356 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- BAZ2A | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 148/789 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND7 | c.963A>C p.R321S | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CADPS | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 225/354 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CARMIL2 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 160/160 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.214); called by muse, varscan2
- CARMIL2 | c.2083-1G>A p.X695_splice | Splice Site (SNP) | VAF 197/198 reads (99%) | called by muse, varscan2
- CCDC141 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 280/379 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.17); called by muse, varscan2
- CCDC168 | c.11614G>A p.E3872K | Missense Mutation (SNP) | VAF 168/263 reads (64%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- CEMIP | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 109/884 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- CNOT2 | c.400A>T p.M134L | Missense Mutation (SNP) | VAF 90/166 reads (54%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- CNOT2 | c.401T>A p.M134K | Missense Mutation (SNP) | VAF 82/155 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); called by muse, varscan2
- COL10A1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 250/396 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, varscan2
- CORO2A | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 125/125 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CR1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 240/543 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, varscan2
- DCHS1 | c.8387_8388del p.S2796Cfs*12 | Frame Shift Del (DEL) | VAF 99/507 reads (20%) | called by pindel, varscan2
- DIO2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 180/280 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, varscan2
- DMD | c.2254A>G p.K752E | Missense Mutation (SNP) | VAF 122/237 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); called by muse, varscan2
- DNAH2 | c.7250C>T p.P2417L | Missense Mutation (SNP) | VAF 298/299 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); called by muse, varscan2
- DNAH8 | c.9844G>A p.G3282S | Missense Mutation (SNP) | VAF 156/332 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0.264); called by muse, varscan2
- DTWD2 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 404/404 reads (100%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, varscan2
- DTX1 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 468/793 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.254); called by muse, varscan2
- ELAVL2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, varscan2
- FAM71E2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 233/580 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLGA3 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 233/604 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); called by muse, varscan2
- HEATR3 | c.577T>C p.Y193H | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, varscan2
- HHIPL2 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 127/242 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- HOXA13 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 253/873 reads (29%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 235/462 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HTR1B | c.1103T>G p.I368S | Missense Mutation (SNP) | VAF 168/253 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- IFT122 | c.1066C>T p.H356Y (on ENST00000348417 / NM_052989.3; = p.H297Y on NM_018262.4) | Missense Mutation (SNP) | VAF 200/314 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IP6K3 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IQCF1 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 81/149 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- ITGA9 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 169/253 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ITK | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 176/176 reads (100%) | called by muse, varscan2
- KANSL3 | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 172/242 reads (71%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, varscan2
- KCNJ15 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.094); called by muse, varscan2
- KIRREL3 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 167/261 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, varscan2
- L1TD1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 138/288 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LMAN2L | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC8B | c.1323A>C p.E441D | Missense Mutation (SNP) | VAF 181/379 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, varscan2
- MAGED1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.679); called by muse, varscan2
- MARK3 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 157/220 reads (71%) | SIFT tolerated (0.31); PolyPhen benign (0.402); called by muse, varscan2
- MMP28 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 362/366 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, varscan2
- MMRN1 | c.2853T>A p.H951Q | Missense Mutation (SNP) | VAF 224/440 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, varscan2
- MROH7 | c.501C>G p.N167K | Missense Mutation (SNP) | VAF 242/543 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- NAV3 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, varscan2
- NDST4 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 66/310 reads (21%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); called by muse, varscan2
- NOL4 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 107/325 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- OGFOD2 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 174/470 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, varscan2
- OR10H1 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 248/432 reads (57%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.963); called by muse, varscan2
- OR10S1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 260/382 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, varscan2
- OR51Q1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 220/409 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OXNAD1 | c.-8-8T>G | Splice Region (SNP) | VAF 239/370 reads (65%) | called by muse, varscan2
- PAPLN | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, varscan2
- PAPPA2 | c.5191C>T p.Q1731* | Nonsense Mutation (SNP) | VAF 211/469 reads (45%) | called by muse, mutect2, varscan2
- PGK2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 202/326 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- PGPEP1L | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 215/854 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, varscan2
- PIP5K1A | c.1102C>T p.Q368* (on ENST00000368888 / NM_001135638.2; = p.Q355* on NM_003557.3) | Nonsense Mutation (SNP) | VAF 169/350 reads (48%) | called by muse, mutect2, varscan2
- POM121L2 | c.2990C>T p.S997F | Missense Mutation (SNP) | VAF 228/466 reads (49%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.519); called by muse, varscan2
- PPID | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 188/365 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRKAG2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 195/973 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PRKG2 | c.2171T>A p.L724H | Missense Mutation (SNP) | VAF 124/252 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- PRMT8 | c.766A>C p.K256Q | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROS1 | c.2010G>A p.W670* | Nonsense Mutation (SNP) | VAF 90/212 reads (42%) | called by muse, mutect2
- PSG9 | c.394A>G p.R132G | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN22 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 156/321 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRK | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, varscan2
- PTPRQ | c.4228G>A p.G1410R (on ENST00000616559; = p.G1368R on NM_001145026.2) | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASA3 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASSF10 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 209/799 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- RBMXL2 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 358/764 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.013); called by muse, varscan2
- REELD1 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 218/466 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, varscan2
- RIMS1 | c.4157G>A p.R1386K | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- RINL | c.1168C>T p.P390S (on ENST00000591812 / NM_001195833.2; = p.P276S on NM_198445.4) | Missense Mutation (SNP) | VAF 381/714 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RTP2 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 136/444 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SCFD1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SCN11A | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 95/310 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SDSL | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 336/624 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SEMA5A | c.1790G>C p.G597A | Missense Mutation (SNP) | VAF 187/286 reads (65%) | SIFT tolerated (0.38); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SHMT1 | c.1350G>C p.E450D | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC30A8 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 188/417 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLFN11 | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 200/200 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SPANXB1 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 96/740 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SSU72P8 | c.253T>A p.L85M | Missense Mutation (SNP) | VAF 252/648 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- STAP2 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 152/252 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, varscan2
- TARBP2 | c.628A>T p.K210* (on ENST00000266987 / NM_134323.2; = p.K189* on NM_004178.4) | Nonsense Mutation (SNP) | VAF 67/209 reads (32%) | called by muse, varscan2
- TDG | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 78/285 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TFCP2L1 | c.292-1_292insC p.S98Qfs*9 | Frame Shift Ins (INS) | VAF 242/453 reads (53%) | called by mutect2, pindel, varscan2
- TGM6 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TMCC3 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 205/566 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TMEM132C | c.1912G>T p.G638W | Missense Mutation (SNP) | VAF 248/402 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132C | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 412/704 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TOPAZ1 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TPSAB1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 124/524 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.162); called by muse, varscan2
- TRAV9-1 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, varscan2
- TRBV24-1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 150/852 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); called by muse, varscan2
- TTN | c.23845T>A p.F7949I (on ENST00000591111; = p.F7022I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 205/284 reads (72%) | PolyPhen benign (0.172); called by muse, mutect2, varscan2
- VWC2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 439/1207 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.197); called by muse, varscan2
- WDR97 | c.4814C>T p.P1605L | Missense Mutation (SNP) | VAF 90/824 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- ZBTB16 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 127/370 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF169 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 287/292 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF260 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 170/370 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, varscan2
- ZNF711 | c.2008C>T p.H670Y | Missense Mutation (SNP) | VAF 238/356 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF774 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 122/452 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ABCC1 | c.2373C>T p.F791= | Silent (SNP) | VAF 354/724 reads (49%) | catalogued as rs748257791, COSV100579890; called by muse, mutect2, varscan2
- ADAMTSL4 | c.417G>A p.E139= | Silent (SNP) | VAF 148/307 reads (48%) | catalogued as rs1299076621; called by muse, varscan2
- AFDN | c.4620C>T p.I1540= | Silent (SNP) | VAF 116/380 reads (31%) | called by muse, varscan2
- AHSA1 | c.207C>T p.S69= | Silent (SNP) | VAF 118/343 reads (34%) | called by muse, mutect2, varscan2
- ANKRD33 | c.39C>T p.A13= (on ENST00000340970 / NM_001304459.2; = p.A148= on NM_182608.4) | Silent (SNP) | VAF 983/1204 reads (82%) | called by muse, varscan2
- ANKRD61 | c.90G>A p.S30= | Silent (SNP) | VAF 233/720 reads (32%) | catalogued as rs1324997677, COSV52240803; called by muse, mutect2, varscan2
- ANKS1B | c.1116A>T p.G372= | Silent (SNP) | VAF 66/336 reads (20%) | called by muse, mutect2, varscan2
- ANO2 | c.2676G>A p.S892= (on ENST00000356134 / NM_001278597.3; = p.S896= on NM_001278596.3) | Silent (SNP) | VAF 201/292 reads (69%) | catalogued as rs1179397959, COSV59019081; called by muse, varscan2
- ATG2B | c.3753C>T p.P1251= | Silent (SNP) | VAF 114/174 reads (66%) | called by muse, varscan2
- ATG9B | c.72G>A p.S24= | Silent (SNP) | VAF 858/858 reads (100%) | catalogued as rs1239776376; called by muse, mutect2, varscan2
- C19orf57 | c.1221C>T p.P407= | Silent (SNP) | VAF 267/529 reads (50%) | called by muse, mutect2, varscan2
- CACNA1E | c.1033C>T p.L345= | Silent (SNP) | VAF 148/285 reads (52%) | catalogued as rs745797769; called by muse, mutect2, varscan2
- CELSR1 | c.3174C>T p.A1058= | Silent (SNP) | VAF 124/397 reads (31%) | catalogued as COSV53097860; called by muse, varscan2
- CELSR3 | c.6810C>T p.A2270= | Silent (SNP) | VAF 242/402 reads (60%) | catalogued as rs1177194655; called by muse, varscan2
- CFAP58 | c.1266G>A p.Q422= | Silent (SNP) | VAF 190/190 reads (100%) | called by muse, varscan2
- CNDP2 | c.1026C>T p.I342= | Silent (SNP) | VAF 101/327 reads (31%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3663G>A p.G1221= | Silent (SNP) | VAF 76/306 reads (25%) | catalogued as COSV70472957; called by muse, mutect2, varscan2
- COL5A3 | c.3165G>A p.G1055= | Silent (SNP) | VAF 232/432 reads (54%) | called by muse, varscan2
- CPNE4 | c.315G>A p.L105= | Silent (SNP) | VAF 209/308 reads (68%) | catalogued as rs371737129; called by muse, varscan2
- CRISP3 | c.87C>T p.F29= (on ENST00000371159 / NM_001368123.1; = p.F21= on NM_001190986.2) | Silent (SNP) | VAF 130/380 reads (34%) | catalogued as rs868746593; called by muse, mutect2, varscan2
- DNAAF1 | c.1587G>A p.T529= | Silent (SNP) | VAF 184/186 reads (99%) | catalogued as rs769031288; called by muse, varscan2
- DNAAF6 | c.570C>T p.F190= | Silent (SNP) | VAF 145/256 reads (57%) | called by muse, mutect2, varscan2
- DNAH5 | c.8121C>T p.I2707= | Silent (SNP) | VAF 235/352 reads (67%) | catalogued as COSV54213016; called by muse, varscan2
- DOCK9 | c.5781C>T p.F1927= (on ENST00000376460 / NM_001366676.2; = p.F1928= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 169/247 reads (68%) | called by muse, mutect2, varscan2
- EFHC2 | c.561C>T p.P187= | Silent (SNP) | VAF 204/306 reads (67%) | called by muse, varscan2
- EFL1 | c.1626C>T p.F542= | Silent (SNP) | VAF 77/376 reads (20%) | catalogued as rs368724353; called by muse, mutect2, varscan2
- ELL | c.459C>T p.G153= | Silent (SNP) | VAF 116/283 reads (41%) | called by muse, varscan2
- ELOA3C | c.741G>A p.E247= | Silent (SNP) | VAF 159/1738 reads (9%) | called by muse, varscan2
- EPHA6 | c.501C>T p.Y167= | Silent (SNP) | VAF 166/234 reads (71%) | catalogued as rs1049029555, COSV67568236, COSV67582146; called by muse, varscan2
- EPS8L3 | c.1455G>A p.R485= (on ENST00000361965 / NM_133181.4; = p.R455= on NM_024526.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 160/324 reads (49%) | called by muse, varscan2
- EVPL | c.486G>A p.Q162= | Silent (SNP) | VAF 117/244 reads (48%) | catalogued as rs1320767218; called by muse, mutect2, varscan2
- FAM170B | c.165G>A p.R55= | Silent (SNP) | VAF 228/228 reads (100%) | called by muse, varscan2
- FAM71D | c.702C>T p.F234= | Silent (SNP) | VAF 202/297 reads (68%) | catalogued as rs891376287, COSV61295401; called by muse, mutect2, varscan2
- FCRL5 | c.1185C>T p.A395= | Silent (SNP) | VAF 174/362 reads (48%) | called by muse, varscan2
- FOXO4 | c.459G>A p.S153= | Silent (SNP) | VAF 90/304 reads (30%) | catalogued as rs761311748, COSV100447144; called by muse, varscan2
- FRMPD3 | c.3276C>T p.F1092= | Silent (SNP) | VAF 175/558 reads (31%) | catalogued as COSV52187365; called by muse, varscan2
- GFI1 | c.252G>A p.S84= | Silent (SNP) | VAF 318/616 reads (52%) | called by muse, varscan2
- GON4L | c.1878C>T p.T626= | Silent (SNP) | VAF 105/258 reads (41%) | called by muse, varscan2
- GPR173 | c.894C>A p.L298= | Silent (SNP) | VAF 187/568 reads (33%) | called by muse, varscan2
- HIF3A | c.1074A>G p.Q358= (on ENST00000377670 / NM_152795.4; = p.Q289= on NM_022462.4) | Silent (SNP) | VAF 230/385 reads (60%) | called by muse, mutect2, varscan2
- HOXD13 | c.939G>A p.T313= | Silent (SNP) | VAF 323/441 reads (73%) | catalogued as rs150319624; called by muse, mutect2, varscan2
- HTR5A | c.114C>T p.V38= | Silent (SNP) | VAF 299/874 reads (34%) | catalogued as COSV99839355; called by muse, varscan2
- ICE1 | c.6075T>G p.S2025= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as rs1369258398; called by muse, mutect2, varscan2
- IFIT3 | c.1371C>T p.F457= | Silent (SNP) | VAF 222/222 reads (100%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.183G>A p.G61= | Silent (SNP) | VAF 162/343 reads (47%) | catalogued as rs782257798; called by muse, varscan2
- IL17RB | c.405C>T p.F135= | Silent (SNP) | VAF 88/322 reads (27%) | called by muse, mutect2
- ITPR2 | c.2940C>T p.I980= | Silent (SNP) | VAF 128/189 reads (68%) | called by muse, varscan2
- KDR | c.1875G>A p.L625= | Silent (SNP) | VAF 196/382 reads (51%) | called by muse, varscan2
- KIF26B | c.1434G>A p.K478= | Silent (SNP) | VAF 306/667 reads (46%) | called by muse, mutect2, varscan2
- KIR2DS4 | c.117G>A p.V39= | Silent (SNP) | VAF 165/166 reads (99%) | called by muse, mutect2, varscan2
- KITLG | c.90G>A p.R30= | Silent (SNP) | VAF 210/392 reads (54%) | catalogued as COSV57201358; called by muse, mutect2, varscan2
- KLHL20 | c.798C>T p.F266= | Silent (SNP) | VAF 144/288 reads (50%) | called by muse, varscan2
- KLK12 | c.498C>T p.I166= | Silent (SNP) | VAF 208/371 reads (56%) | catalogued as COSV51578982; called by muse, varscan2
- LAMA1 | c.2343C>T p.S781= | Silent (SNP) | VAF 124/427 reads (29%) | called by muse, varscan2
- LCT | c.2514C>T p.F838= | Silent (SNP) | VAF 367/496 reads (74%) | catalogued as COSV51548641; called by muse, varscan2
- LGALS14 | c.189C>T p.I63= | Silent (SNP) | VAF 172/392 reads (44%) | catalogued as rs1196918495, COSV62372188; called by muse, varscan2
- LRP1B | c.9387G>A p.L3129= | Silent (SNP) | VAF 309/442 reads (70%) | catalogued as rs1432038864; called by muse, mutect2, varscan2
- LRRC14B | c.489C>T p.F163= | Silent (SNP) | VAF 356/497 reads (72%) | catalogued as rs534002505, COSV52045776; called by muse, varscan2
- MGAM2 | c.2700C>T p.F900= | Silent (SNP) | VAF 181/885 reads (20%) | called by muse, mutect2, varscan2
- MIER2 | c.234C>T p.F78= | Silent (SNP) | VAF 162/272 reads (60%) | called by muse, mutect2, varscan2
- MPEG1 | c.432A>G p.Q144= | Silent (SNP) | VAF 192/298 reads (64%) | called by muse, varscan2
- MTSS1 | c.711C>A p.P237= | Silent (SNP) | VAF 77/406 reads (19%) | called by muse, mutect2, varscan2
- MUC12 | c.7260C>T p.A2420= (on ENST00000379442; = p.A2277= on NM_001164462.1) | Silent (SNP) | VAF 312/2544 reads (12%) | called by muse, varscan2
- MUC16 | c.1782C>T p.S594= | Silent (SNP) | VAF 168/425 reads (40%) | called by muse, mutect2, varscan2
- MUC6 | c.162C>T p.S54= | Silent (SNP) | VAF 302/636 reads (47%) | called by muse, varscan2
- MYEOV | c.546G>A p.E182= | Silent (SNP) | VAF 165/491 reads (34%) | catalogued as rs762846844; called by muse, mutect2, varscan2
- MYO1A | c.2310G>A p.E770= | Silent (SNP) | VAF 61/191 reads (32%) | called by muse, mutect2, varscan2
- MYO7B | c.4599G>A p.K1533= | Silent (SNP) | VAF 344/448 reads (77%) | catalogued as rs903286610; called by muse, varscan2
- MYOT | c.276C>T p.S92= | Silent (SNP) | VAF 269/269 reads (100%) | called by muse, varscan2
- NAP1L3 | c.513C>T p.F171= | Silent (SNP) | VAF 164/550 reads (30%) | called by muse, mutect2, varscan2
- NBPF12 | c.390C>T p.L130= | Silent (SNP) | VAF 218/670 reads (33%) | catalogued as rs1429121487; called by muse, varscan2
- NEK11 | c.837C>T p.I279= | Silent (SNP) | VAF 56/254 reads (22%) | catalogued as rs769704761; called by muse, mutect2, varscan2
- NLRP10 | c.1338C>T p.F446= | Silent (SNP) | VAF 294/642 reads (46%) | catalogued as rs1189324356, COSV60781977; called by muse, varscan2
- NLRP12 | c.1086C>T p.I362= | Silent (SNP) | VAF 220/392 reads (56%) | called by muse, mutect2, varscan2
- NPC1L1 | c.2202C>T p.V734= | Silent (SNP) | VAF 228/709 reads (32%) | called by muse, mutect2, varscan2
- NPNT | c.1531C>T p.L511= | Silent (SNP) | VAF 252/466 reads (54%) | called by muse, varscan2
- OR11L1 | c.660C>T p.F220= | Silent (SNP) | VAF 188/378 reads (50%) | catalogued as COSV63313450, COSV63314124; called by muse, varscan2
- OR2I1P | c.48C>T p.F16= | Silent (SNP) | VAF 228/422 reads (54%) | called by muse, varscan2
- OR52L1 | c.42G>A p.L14= | Silent (SNP) | VAF 212/428 reads (50%) | catalogued as COSV59989885; called by muse, varscan2
- P3H1 | c.249C>T p.F83= | Silent (SNP) | VAF 494/922 reads (54%) | called by muse, varscan2
- PEX6 | c.756T>A p.S252= | Silent (SNP) | VAF 293/566 reads (52%) | called by muse, varscan2
- PKHD1L1 | c.549G>A p.G183= | Silent (SNP) | VAF 151/254 reads (59%) | catalogued as rs1329747913, COSV65748593; called by muse, varscan2
- PLXNA3 | c.579G>A p.A193= | Silent (SNP) | VAF 102/356 reads (29%) | catalogued as rs367789508, COSV100859840, COSV63755056; called by muse, varscan2
- POLR1C | c.450C>T p.P150= | Silent (SNP) | VAF 218/444 reads (49%) | catalogued as rs767689208; called by muse, varscan2
- POTEE | c.864G>A p.V288= | Silent (SNP) | VAF 99/642 reads (15%) | catalogued as rs1326371615, COSV58235590; called by muse, mutect2, varscan2
- PRAMEF19 | c.900A>G p.L300= | Silent (SNP) | VAF 297/453 reads (66%) | called by muse, varscan2
- PRICKLE3 | c.1704C>T p.I568= | Silent (SNP) | VAF 174/588 reads (30%) | called by muse, mutect2, varscan2
- PTGFR | c.153C>T p.L51= | Silent (SNP) | VAF 230/509 reads (45%) | called by muse, varscan2
- PTPRB | c.867C>T p.P289= | Silent (SNP) | VAF 126/184 reads (68%) | catalogued as COSV54250456, COSV99717561; called by muse, varscan2
- PTX3 | c.1077C>T p.I359= | Silent (SNP) | VAF 247/380 reads (65%) | called by muse, mutect2, varscan2
- RAB44 | c.1299G>A p.R433= | Silent (SNP) | VAF 321/614 reads (52%) | called by muse, varscan2
- RERE | c.3129C>T p.G1043= | Silent (SNP) | VAF 246/780 reads (32%) | catalogued as rs1305864548, COSV61945231; called by muse, varscan2
- RFX7 | c.876A>G p.K292= (on ENST00000559447 / NM_001368074.1; = p.K389= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 218/449 reads (49%) | called by muse, mutect2, varscan2
- RNF113A | c.57C>T p.F19= | Silent (SNP) | VAF 161/461 reads (35%) | catalogued as COSV65098010; called by muse, mutect2, varscan2
- SCN10A | c.3075C>T p.I1025= | Silent (SNP) | VAF 56/192 reads (29%) | catalogued as COSV71862710; called by muse, varscan2
- SCN7A | c.3915C>T p.F1305= | Silent (SNP) | VAF 91/354 reads (26%) | called by muse, mutect2, varscan2
- SDSL | c.285C>T p.P95= | Silent (SNP) | VAF 329/620 reads (53%) | catalogued as rs768332846; called by muse, varscan2
- SETD7 | c.984C>T p.I328= | Silent (SNP) | VAF 197/442 reads (45%) | called by muse, mutect2, varscan2
- SHROOM2 | c.4227G>C p.L1409= | Silent (SNP) | VAF 332/1570 reads (21%) | called by muse, mutect2, varscan2
- SLAMF8 | c.291C>T p.D97= | Silent (SNP) | VAF 299/578 reads (52%) | catalogued as rs1298033043; called by muse, mutect2, varscan2
- SLC17A2 | c.1224C>T p.F408= (on ENST00000265425; = p.S359F on NM_005835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 167/344 reads (49%) | called by muse, mutect2, varscan2
- SOBP | c.147T>C p.D49= | Silent (SNP) | VAF 184/296 reads (62%) | called by muse, varscan2
- SPTB | c.4746C>T p.D1582= | Silent (SNP) | VAF 286/460 reads (62%) | catalogued as rs760026396, COSV67630440; called by muse, varscan2
- STARD6 | c.96G>A p.K32= | Silent (SNP) | VAF 115/169 reads (68%) | called by muse, mutect2, varscan2
- STEAP2 | c.12C>T p.I4= | Silent (SNP) | VAF 87/320 reads (27%) | called by muse, mutect2, varscan2
- STK11IP | c.843C>T p.L281= | Silent (SNP) | VAF 207/291 reads (71%) | catalogued as rs1483758915; called by muse, mutect2, varscan2
- SYNE1 | c.25563G>A p.Q8521= (on ENST00000367255 / NM_182961.4; = p.Q8473= on NM_033071.3) | Silent (SNP) | VAF 150/462 reads (32%) | called by muse, varscan2
- TAF4 | c.513C>T p.G171= | Silent (SNP) | VAF 12/44 reads (27%) | called by muse, varscan2
- TAS2R1 | c.597C>T p.F199= | Silent (SNP) | VAF 179/292 reads (61%) | called by muse, varscan2
- TESK1 | c.1278C>T p.V426= | Silent (SNP) | VAF 753/753 reads (100%) | called by muse, varscan2
- TINAG | c.1155C>T p.F385= | Silent (SNP) | VAF 144/216 reads (67%) | catalogued as rs1300632056, COSV99450794; called by muse, mutect2, varscan2
- TLN2 | c.2670G>A p.Q890= | Silent (SNP) | VAF 190/729 reads (26%) | catalogued as rs1448071936; called by muse, varscan2
- TLR4 | c.864C>T p.F288= (on ENST00000355622 / NM_138554.5; = p.F248= on NM_003266.4) | Silent (SNP) | VAF 174/174 reads (100%) | catalogued as rs909813445; called by muse, varscan2
- TNIK | c.735C>T p.I245= | Silent (SNP) | VAF 168/270 reads (62%) | catalogued as rs1211378611; called by muse, varscan2
- TPBG | c.1038G>A p.P346= | Silent (SNP) | VAF 100/334 reads (30%) | called by muse, varscan2
- TRAV9-1 | c.153C>T p.S51= | Silent (SNP) | VAF 74/355 reads (21%) | called by muse, mutect2, varscan2
- TRBV19 | c.39C>T p.L13= | Silent (SNP) | VAF 181/899 reads (20%) | called by muse, mutect2, varscan2
- TRBV3-1 | c.93C>T p.V31= | Silent (SNP) | VAF 514/929 reads (55%) | called by muse, varscan2
- TTBK1 | c.27G>A p.K9= | Silent (SNP) | VAF 195/424 reads (46%) | catalogued as rs751441680, COSV52497963; called by muse, varscan2
- UNC13C | c.5589C>T p.F1863= | Silent (SNP) | VAF 132/252 reads (52%) | catalogued as rs764281925, COSV52858952; called by muse, varscan2
- UNC79 | c.2676C>T p.S892= (on ENST00000393151 / NM_001346218.2; = p.S715= on NM_020818.5) | Silent (SNP) | VAF 74/261 reads (28%) | called by muse, varscan2
- UROC1 | c.804G>A p.V268= | Silent (SNP) | VAF 88/340 reads (26%) | catalogued as COSV52039354; called by muse, mutect2, varscan2
- USH2A | c.11691C>T p.I3897= | Silent (SNP) | VAF 130/272 reads (48%) | called by muse, mutect2, varscan2
- WDR87 | c.4314G>A p.E1438= | Silent (SNP) | VAF 218/378 reads (58%) | catalogued as COSV58206598; called by muse, varscan2
- WDR87 | c.4224G>A p.Q1408= | Silent (SNP) | VAF 142/372 reads (38%) | called by muse, varscan2
- WEE2 | c.408G>A p.L136= | Silent (SNP) | VAF 303/1397 reads (22%) | catalogued as COSV66878917; called by muse, mutect2, varscan2
- ZNF462 | c.2973C>T p.S991= | Silent (SNP) | VAF 206/206 reads (100%) | called by muse, varscan2
- ZNF724 | c.147G>A p.K49= | Silent (SNP) | VAF 41/174 reads (24%) | catalogued as COSV101369925; called by muse, mutect2, varscan2
- ZSWIM3 | c.702C>T p.L234= | Silent (SNP) | VAF 168/275 reads (61%) | catalogued as rs762881127; called by muse, varscan2
- ACSL5 | c.-136G>A | 5'UTR (SNP) | VAF 212/212 reads (100%) | called by muse, varscan2
- ARMCX4 | c.1038+2005C>T | Intron (SNP) | VAF 400/717 reads (56%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*273G>A | 3'UTR (SNP) | VAF 132/399 reads (33%) | called by muse, mutect2, varscan2
- CEP89 | c.39+376T>G | Intron (SNP) | VAF 139/257 reads (54%) | called by muse, mutect2, varscan2
- DNAH7 | c.1353+1606C>T | Intron (SNP) | VAF 55/303 reads (18%) | catalogued as rs1368464110; called by muse, mutect2, varscan2
- DSCR4 | n.411G>A | RNA (SNP) | VAF 86/329 reads (26%) | catalogued as COSV100077261, COSV60301610; called by muse, mutect2, varscan2
- LCE3C | c.-42C>T | 5'UTR (SNP) | VAF 280/540 reads (52%) | called by muse, varscan2
- MARCHF1 | c.242+810G>A | Intron (SNP) | VAF 221/435 reads (51%) | called by muse, mutect2, varscan2
- OPRM1 | c.-490C>T | 5'UTR (SNP) | VAF 88/236 reads (37%) | called by muse, varscan2
- PDE2A | c.71+5827C>T | Intron (SNP) | VAF 118/354 reads (33%) | catalogued as rs764845633, COSV57810022; called by muse, mutect2, varscan2
- SEPTIN3 | chr22:41972532 G>A | 5'Flank (SNP) | VAF 194/479 reads (41%) | called by muse, varscan2
- SIGLEC5 | c.*1G>T | 3'UTR (SNP) | VAF 61/201 reads (30%) | called by muse, mutect2, varscan2
- SLC6A19 | c.*352G>A | 3'UTR (SNP) | VAF 203/321 reads (63%) | catalogued as rs1171294721; called by muse, mutect2, varscan2
- THSD4 | c.-80+14329C>T | Intron (SNP) | VAF 530/789 reads (67%) | catalogued as rs375345437, COSV100804218; called by muse, varscan2
- TTN | c.10360+1393G>A | Intron (SNP) | VAF 109/461 reads (24%) | catalogued as rs754287881, COSV59985124; called by muse, mutect2, varscan2
- USH1C | c.1284+5449G>A | Intron (SNP) | VAF 180/420 reads (43%) | called by muse, varscan2
- WBP2 | c.532+28C>T | Intron (SNP) | VAF 269/270 reads (100%) | called by muse, mutect2, varscan2
